Gene-level copy-number profile of tumor specimen TCGA-B6-A0IA-01A from TCGA case TCGA-B6-A0IA, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct mixed with other types of carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 51.3 years (18,748 days).
Specimen TCGA-B6-A0IA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.8b4314b3-0f2a-4451-87ff-ad498c7a1ab9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B6-A0IA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5c9d7cb8-7aaf-4a91-81b5-70513388e9f8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,406; copy number 2: 45,579; copy number 3: 3,910; copy number 4: 2,327; copy number 5: 3,461; copy number 6: 135; copy number 7: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B6-A0IA-01A-11D-A036-01): tumor purity 0.91, ploidy 2.17, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,597 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:219,962,652–220,090,462, 3 genes, copy number 5: U3, EPRS1, BPNT1.
- chr1:234,979,647–248,362,627, 297 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr6:10,459,906–16,295,549, 103 genes, copy number 5 (broad region; genes not listed).
- chr6:17,615,035–26,659,752, 187 genes, copy number 5–6 (within-gene range 1–6) (broad region; genes not listed).
- chr8:30,578,318–54,420,725, 381 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr8:68,293,446–145,066,685, 1,200 genes, copy number 5 (broad region; genes not listed).
- chr16:11,555–3,611,606, 334 genes, copy number 5 (broad region; genes not listed).
- chr16:3,725,054–35,912,516, 1,081 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr16:49,072,543–49,469,875, 10 genes, copy number 6 (within-gene range 2–6): AC044798.3, AC044798.1, AC044798.2, CBLN1, AC007614.1, AC007614.2, C16orf78, AC007861.1, AC007861.2, LINC02179.
- chr16:49,517,762–49,518,601, 1 gene, copy number 6: ADAM3B.

Autosomal genes at a single copy (total copy number 1): 4,406. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
